Somatic mutation profile of tumor specimen TCGA-UY-A9PE-01A (aliquot TCGA-UY-A9PE-01A-11D-A38G-08) from TCGA case TCGA-UY-A9PE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 86.9 years (31,755 days).
Specimen TCGA-UY-A9PE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f09880c-b33b-4f53-a39f-030cd201fcbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A9PE-10A (Blood Derived Normal), aliquot TCGA-UY-A9PE-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79e6d789-82d7-4acd-99ee-df83bf65f8c7

The open-access MAF lists 228 somatic variants for this specimen: 173 protein-altering or splice-affecting, 46 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 46, Nonsense Mutation 14, Intron 4, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 2, RNA 2, 5'UTR 2, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as rs786204910, CM110130, CM1513152, COSV64288346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370588279, CM030956, COSV55914262; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 30/49 reads (61%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- ABCA4 | c.4996G>A p.E1666K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs773880325, COSV64676943; called by muse, varscan2
- ABCA4 | c.4948G>A p.E1650K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.472); catalogued as rs762754528, CM161731, COSV64676947; ClinVar: uncertain significance; called by muse, varscan2
- AC126283.2 | c.1329T>G p.D443E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67099664; called by muse, mutect2, varscan2
- ADCY1 | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs757148044, COSV52040971; called by muse, mutect2, varscan2
- ADNP | c.2464G>T p.V822L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62426607, COSV62427150; called by muse, mutect2, varscan2
- AFF2 | c.2391C>A p.N797K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV54003783, COSV99661279; called by muse, mutect2, varscan2
- AHCTF1 | c.5168C>T p.T1723I (on ENST00000366508; = p.T1697I on NM_015446.5) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as COSV58254144; called by muse, mutect2, varscan2
- ANKIB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs1175740002, COSV99728670; called by muse, mutect2, varscan2
- AOC3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV53828427; called by muse, mutect2, varscan2
- APBB1 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54970234; called by muse, mutect2, varscan2
- AQR | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV50048229; called by muse, mutect2, varscan2
- ARFGEF1 | c.5218G>C p.D1740H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51615651; called by muse, mutect2, varscan2
- ARIH2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as COSV100711258; called by muse, mutect2, varscan2
- ATP1A3 | c.2788G>A p.V930I (on ENST00000545399 / NM_001256214.2; = p.V917I on NM_152296.5) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV57488331; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100376900; called by muse, mutect2, varscan2
- BACH2 | c.2096T>G p.M699R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV57604744; called by muse, mutect2, varscan2
- BNC1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61758845; called by muse, mutect2, varscan2
- BRMS1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1194003067, COSV60820601; called by muse, mutect2, varscan2
- BTBD11 | c.2224G>C p.G742R (on ENST00000280758 / NM_001018072.2; = p.G279R on NM_001017523.2) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55036611, COSV99775157, COSV99775219; called by muse, mutect2
- C12orf50 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs1272183478, COSV53893453, COSV53895446; called by muse, mutect2, varscan2
- CA5B | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV59417496; called by muse, mutect2, varscan2
- CCDC158 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV101187189; called by muse, mutect2, varscan2
- CCDC158 | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs767889035, COSV63092560; called by muse, mutect2, varscan2
- CCDC181 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1273343177, COSV63157790; called by muse, mutect2, varscan2
- CCM2 | c.746-1G>C p.X249_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51850808; called by muse, mutect2, varscan2
- CEP152 | c.4697G>C p.G1566A (on ENST00000380950 / NM_001194998.2; = p.G1510A on NM_014985.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs920499634, COSV57863406; called by muse, mutect2, varscan2
- CHD6 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV58561342; called by muse, varscan2
- CLASP1 | c.3016G>T p.A1006S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV99753787; called by muse, mutect2
- CNIH4 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481927460, COSV64796457; called by muse, mutect2, varscan2
- COL4A1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs758969549, COSV65427189; called by muse, mutect2, varscan2
- CPT2 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV53760179; called by muse, mutect2, varscan2
- CTNND1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs1397287146, COSV62385576; called by muse, mutect2, varscan2
- CUL1 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57391756; called by muse, mutect2, varscan2
- CYP2J2 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as rs777048725, COSV64607005; called by muse, mutect2, varscan2
- DDRGK1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs763621314, COSV63227324; called by muse, mutect2, varscan2
- DENND4B | c.3560G>A p.C1187Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63411403; called by muse, varscan2
- DIDO1 | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56632167; called by muse, mutect2, varscan2
- DLC1 | c.1759G>A p.E587K (on ENST00000276297 / NM_001348081.2; = p.E150K on NM_006094.5) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs767485912, COSV52323481; called by muse, varscan2
- DLGAP1 | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59829667; called by muse, mutect2, varscan2
- DNA2 | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV64429860; called by muse, mutect2, varscan2
- DNAH2 | c.12523C>G p.Q4175E | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV66725168; called by muse, mutect2, varscan2
- DSN1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious, low confidence (0.01); catalogued as COSV65520017; called by muse, mutect2, varscan2
- DTX3L | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145286; called by muse, mutect2, varscan2
- EP300 | c.6182C>T p.P2061L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54342674; called by muse, mutect2, varscan2
- EYA4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as COSV62058538; called by muse, mutect2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 21/91 reads (23%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM160B1 | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65089335; called by muse, mutect2, varscan2
- FAM83H | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1363134701, COSV66354507; called by muse, mutect2, varscan2
- FAP | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1404180579, COSV51866567; called by muse, mutect2, varscan2
- FAT4 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.994); catalogued as COSV101272168; called by muse, mutect2
- GAB1 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53760117; called by muse, mutect2, varscan2
- GJA10 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as COSV65355988, COSV65356146; called by muse, mutect2, varscan2
- GLT1D1 | c.1036G>A p.D346N (on ENST00000442111 / NM_001366889.1; = p.D266N on NM_144669.3) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV55886660; called by muse, mutect2, varscan2
- H3C6 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV64519644, COSV64519726; called by muse, mutect2, varscan2
- H4C12 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- HEATR5A | c.6141del p.*2047Cfs*12 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs1283250268; called by mutect2, pindel, varscan2
- HIVEP2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50044830; called by muse, mutect2
- HMCN1 | c.13930G>A p.G4644R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs930780704, COSV54933055; called by muse, mutect2, varscan2
- HUWE1 | c.6826G>A p.E2276K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV53350085, COSV53361121; called by muse, mutect2, varscan2
- ICE1 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99664164; called by muse, mutect2
- IGFBP7 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55274986, COSV55276022; called by muse, mutect2, varscan2
- IGSF11 | c.629C>G p.S210* (on ENST00000393775 / NM_001015887.3; = p.S209* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100677157; called by muse, mutect2, varscan2
- INO80 | c.4349G>A p.R1450Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV62739494; called by muse, mutect2, varscan2
- ISG20L2 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57461162; called by muse, mutect2, varscan2
- JARID2 | c.3064G>T p.G1022W | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59196326; called by muse, mutect2, varscan2
- JARID2 | c.3361G>A p.D1121N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); catalogued as COSV100521580; called by muse, mutect2, varscan2
- JMJD4 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs764039645, COSV59917311; called by muse, mutect2, varscan2
- KCNH8 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs199796239, COSV60474138; called by muse, mutect2, varscan2
- KCTD14 | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62002015; called by muse, mutect2, varscan2
- KIF2C | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV64765501; called by muse, mutect2, varscan2
- KRT1 | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52868817; called by muse, mutect2, varscan2
- LAMB2 | c.4093C>T p.R1365W | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751854328, COSV59732648; called by muse, mutect2, varscan2
- LHFPL2 | c.29C>G p.S10W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66714615; called by muse, mutect2
- LPP | c.1383G>C p.K461N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs760883702, COSV57110512; called by muse, mutect2, varscan2
- LRRK1 | c.1885C>G p.Q629E | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs1176065275, COSV52600126; called by muse, mutect2, varscan2
- MAP1LC3A | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV54165625; called by muse, mutect2, varscan2
- MAP3K8 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV53920512, COSV53921331; called by muse, mutect2, varscan2
- MGA | c.5896del p.L1966Ffs*3 (on ENST00000219905 / NM_001164273.1; = p.L1757Ffs*3 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as COSV54950416; called by mutect2, pindel, varscan2
- MGAT5 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs777389323, COSV56100236; called by muse, mutect2, varscan2
- MMP11 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53157660; called by muse, mutect2
- MRPS18C | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.056); catalogued as COSV55027215; called by muse, mutect2, varscan2
- MTBP | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as rs1178239699, COSV59965857, COSV59965864; called by muse, mutect2, varscan2
- MYLK | c.5276C>A p.S1759Y | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60619885; called by muse, mutect2, varscan2
- MYOF | c.5960G>T p.R1987L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63704847, COSV63709503; called by muse, mutect2, varscan2
- MYRF | c.3234G>C p.R1078S (on ENST00000278836 / NM_001127392.3; = p.R1038S on NM_013279.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV53892988; called by muse, mutect2, varscan2
- NFE2L2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs746016111, COSV67960306, COSV67962212; called by muse, mutect2, varscan2
- NME3 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1467003555, COSV51602554; called by muse, mutect2, varscan2
- NOP9 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as COSV51867590; called by muse, mutect2, varscan2
- NPNT | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59756540; called by muse, mutect2, varscan2
- NR3C1 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51546098, COSV99196515; called by muse, mutect2, varscan2
- NUDT7 | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV99215998, COSV99216125; called by muse, mutect2, varscan2
- OR10V1 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV55700547; called by muse, mutect2, varscan2
- OR4M1 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs776023738, COSV100271039, COSV60063335; called by muse, mutect2
- OR4M1 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV60064017; called by muse, mutect2
- OTUD7B | c.1423A>C p.S475R | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as COSV64917561; called by muse, mutect2, varscan2
- PALLD | c.2746G>C p.D916H (on ENST00000505667 / NM_001166108.2; = p.D899H on NM_016081.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV54992054; called by muse, mutect2, varscan2
- PAPPA | c.4085G>A p.C1362Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60290304; called by muse, mutect2, varscan2
- PARP8 | c.1313A>T p.K438M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55865540; called by muse, mutect2, varscan2
- PBLD | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53267088; called by muse, mutect2, varscan2
- PCDH7 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100687844, COSV62339537; called by muse, mutect2
- PCF11 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs938079828, COSV53536844; called by muse, mutect2
- PDE4A | c.2227G>A p.E743K (on ENST00000380702 / NM_001111307.2; = p.E504K on NM_006202.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs758350210, COSV53361104; called by muse, mutect2, varscan2
- PHRF1 | c.1133G>C p.R378T | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV52757792, COSV52761393; called by muse, mutect2, varscan2
- PIGU | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs376729351; called by muse, mutect2, varscan2
- PLAUR | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1165187578, COSV55390599; called by muse, mutect2, varscan2
- PLEKHG2 | c.3315G>C p.Q1105H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV52688786; called by muse, mutect2, varscan2
- PRDM1 | c.2402A>T p.K801M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64846551; called by muse, mutect2, varscan2
- PRMT9 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV59361119; called by muse, mutect2, varscan2
- PRPF38A | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV57123153, COSV99933402; called by muse, mutect2, varscan2
- RBM27 | c.3167G>T p.R1056L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1282125905, COSV54593469; called by muse, mutect2, varscan2
- RBM34 | c.1224_1235del p.L409_T412del | In Frame Del (DEL) | VAF 8/81 reads (10%) | catalogued as COSV64013286; called by mutect2, pindel
- RERGL | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750806416, COSV57463150; called by muse, mutect2, varscan2
- RICTOR | c.5023G>C p.E1675Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57128909; called by muse, mutect2, varscan2
- RNF217 | c.1281G>A p.K427= (on ENST00000521654 / NM_001286398.2; = p.K135= on NM_152553.5) | Splice Region (SNP) | VAF 9/66 reads (14%) | catalogued as rs1311673198, COSV51577241; called by muse, mutect2, varscan2
- RORC | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV59092926; called by muse, mutect2, varscan2
- RYR2 | c.10369G>A p.D3457N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63708015; called by muse, mutect2, varscan2
- RYR2 | c.12873C>G p.F4291L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63678838, COSV63708026; called by muse, mutect2, varscan2
- SACM1L | c.1556G>T p.W519L | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66614757; called by muse, mutect2
- SACM1L | c.1557G>T p.W519C | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV66614763; called by muse, mutect2
- SCPEP1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 137/254 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51855370; called by muse, mutect2, varscan2
- SEC24D | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs149595481; called by muse, mutect2, varscan2
- SEMA3E | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as rs376950350, COSV100319033; called by muse, mutect2, varscan2
- SESN1 | c.1342A>G p.T448A (on ENST00000356644 / NM_001199933.1; = p.T507A on NM_014454.3) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV57421794; called by muse, mutect2, varscan2
- SIGLEC10 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100218678; called by muse, mutect2, varscan2
- SIGLEC10 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59485841; called by muse, mutect2, varscan2
- SIPA1L2 | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1400830017, COSV53397925; called by muse, mutect2, varscan2
- SLC38A10 | c.3010G>T p.G1004W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs767838920, COSV66103160; called by muse, mutect2, varscan2
- SLITRK5 | c.2285A>C p.N762T | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as COSV100280328, COSV100281069, COSV61522559; called by muse, mutect2
- SLK | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.438); catalogued as COSV59828320; called by muse, mutect2, varscan2
- SMARCC1 | c.1926G>T p.W642C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54381802, COSV54385426; called by muse, mutect2, varscan2
- SMCHD1 | c.2420G>A p.R807K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV55266112; called by muse, mutect2, varscan2
- SNX14 | c.1844G>A p.R615K (on ENST00000314673 / NM_001350535.1; = p.R562K on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59015448; called by muse, mutect2, varscan2
- SP100 | c.2168C>G p.S723C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV60849867; called by muse, mutect2, varscan2
- SPAG5 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.368); catalogued as COSV58803931; called by muse, mutect2, varscan2
- SRF | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54839729; called by muse, mutect2, varscan2
- SYDE2 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 64/182 reads (35%) | catalogued as rs768611054, COSV52318935; called by muse, mutect2, varscan2
- TAPBP | c.960C>G p.F320L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV101444945, COSV70457659; called by muse, mutect2, varscan2
- TAX1BP1 | c.1850C>G p.S617* | Nonsense Mutation (SNP) | VAF 19/137 reads (14%) | catalogued as COSV99604285; called by muse, mutect2, varscan2
- TEDC2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99563330; called by muse, mutect2
- TEKT2 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99255431; called by muse, mutect2
- TESK2 | c.1652C>G p.S551* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100517185; called by muse, mutect2, varscan2
- TET1 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV65388643; called by muse, mutect2, varscan2
- TLR4 | c.1114C>A p.L372I (on ENST00000355622 / NM_138554.5; = p.L332I on NM_003266.4) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62923347, COSV62924079; called by muse, mutect2, varscan2
- TMEM168 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV57182166; called by muse, mutect2
- TMPRSS7 | c.1060C>T p.R354W (on ENST00000452346; = p.R228W on NM_001042575.2) | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs566809361, COSV101340156, COSV69982310; called by muse, mutect2, varscan2
- TNNI3K | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.117); catalogued as rs202055411, COSV58554424, COSV58563814; called by muse, mutect2, varscan2
- TP53BP1 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755481776, COSV55504508; called by muse, mutect2, varscan2
- TRPC1 | c.1829G>T p.R610I (on ENST00000476941 / NM_001251845.2; = p.R576I on NM_003304.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV56423434; called by muse, mutect2, varscan2
- TTN | c.46138G>A p.D15380N (on ENST00000591111; = p.D7956N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | PolyPhen probably damaging (0.998); catalogued as COSV60285371; called by muse, mutect2, varscan2
- TTN | c.25784G>A p.S8595N (on ENST00000591111; = p.S7668N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | PolyPhen benign (0.051); catalogued as COSV60285399; called by muse, mutect2, varscan2
- TXNIP | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100997273; called by muse, varscan2
- UBASH3B | c.1920C>G p.F640L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52500996; called by muse, mutect2, varscan2
- UBE3C | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61955262; called by muse, mutect2, varscan2
- USP3 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV51429377; called by muse, mutect2, varscan2
- UTP18 | c.1661C>G p.S554* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99834663; called by muse, mutect2
- UTRN | c.7570G>T p.E2524* | Nonsense Mutation (SNP) | VAF 48/90 reads (53%) | catalogued as COSV100838020; called by muse, mutect2, varscan2
- UTRN | c.9715G>C p.E3239Q | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV62312147; called by muse, mutect2, varscan2
- VPS13D | c.7603C>A p.P2535T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50671286; called by muse, mutect2, varscan2
- VPS8 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as rs1378187611, COSV54994549; called by muse, mutect2, varscan2
- ZBTB46 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV55508601, COSV55513852; called by muse, mutect2, varscan2
- ZDHHC3 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV56102403; called by muse, mutect2, varscan2
- ZDHHC6 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV101024354; called by muse, mutect2, varscan2
- ZNF37A | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs75640170, COSV61075130; called by muse, mutect2, varscan2
- ZNF394 | c.374G>C p.R125P | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV58744278; called by muse, mutect2, varscan2
- ZNF467 | c.1633T>C p.C545R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1398256588, COSV57374546; called by muse, mutect2, varscan2
- ZNF620 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV58820831; called by muse, mutect2, varscan2
- AGAP3 | c.808_819del p.P270_S273del (on ENST00000622464; = p.P306_S309del on NM_031946.7 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel
- CLDN5 | c.186dup p.Q63Afs*190 (on ENST00000618236 / NM_001363066.2; = p.Q148Afs*190 on NM_003277.4) | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- OR11H1 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); called by mutect2, varscan2
- PUS10 | c.849_850del p.A284Sfs*11 | Frame Shift Del (DEL) | VAF 48/410 reads (12%) | called by pindel, varscan2
- ABCA7 | c.5214G>A p.V1738= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV54035993; called by muse, mutect2, varscan2
- ABCC2 | c.2772G>C p.L924= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV64988212; called by muse, mutect2, varscan2
- ALS2CL | c.2358C>T p.F786= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV59673271; called by muse, mutect2, varscan2
- ATOH8 | c.60G>T p.L20= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs745634794, COSV60401822; called by muse, mutect2, varscan2
- ATXN2 | c.3546C>A p.L1182= (on ENST00000550104; = p.L1022= on NM_002973.4) | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV57985950; called by muse, mutect2, varscan2
- CAMK1 | c.516C>A p.G172= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV56540143; called by muse, mutect2, varscan2
- CDH5 | c.432G>A p.V144= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1258582260, COSV58519501; called by muse, mutect2, varscan2
- CDK5 | c.735A>C p.T245= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV52525238; called by muse, mutect2, varscan2
- CSK | c.1128C>G p.L376= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs752992895, COSV54972563; called by muse, mutect2, varscan2
- CST4 | c.258C>T p.D86= | Silent (SNP) | VAF 39/236 reads (17%) | catalogued as rs369432950; called by muse, mutect2, varscan2
- DIDO1 | c.5067G>A p.A1689= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs1434223324, COSV56632160; called by muse, mutect2, varscan2
- DLC1 | c.1716G>A p.P572= (on ENST00000276297 / NM_001348081.2; = p.P135= on NM_006094.5) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs752727723, COSV52304217; called by muse, varscan2
- DLEC1 | c.5178G>A p.V1726= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs543937258, COSV100085951; called by muse, mutect2, varscan2
- DNAH5 | c.390C>T p.F130= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as COSV54246747; called by muse, mutect2, varscan2
- DSCAML1 | c.6279G>C p.S2093= (on ENST00000321322; = p.S2033= on NM_020693.4) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV58400750; called by muse, mutect2, varscan2
- DST | c.7050G>A p.V2350= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV55022040; called by muse, mutect2, varscan2
- ECEL1 | c.1089C>A p.I363= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV58813964; called by muse, mutect2, varscan2
- ERGIC3 | c.1083C>G p.L361= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV53415290; called by muse, varscan2
- FRAS1 | c.2397C>T p.F799= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV53639762; called by muse, mutect2, varscan2
- FZD2 | c.1665C>T p.L555= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs1406510052, COSV59529954; called by muse, mutect2, varscan2
- GTF3C1 | c.2121C>T p.I707= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as rs139483990; called by muse, mutect2, varscan2
- H1-2 | c.441G>A p.P147= | Silent (SNP) | VAF 63/195 reads (32%) | catalogued as COSV59192137, COSV59193598; called by muse, mutect2, varscan2
- IDH3A | c.315C>T p.A105= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs764050752, COSV55112717; called by muse, mutect2, varscan2
- KIAA2026 | c.6264T>A p.P2088= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV67357127; called by muse, mutect2, varscan2
- MEGF6 | c.1401C>T p.F467= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs780082375, COSV53891724; called by muse, mutect2
- MPPE1 | c.600C>T p.N200= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs769337622, COSV57881808, COSV57883403; called by muse, mutect2, varscan2
- MTARC2 | c.636C>G p.L212= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV63766271; called by muse, mutect2, varscan2
- MYLK | c.5277C>G p.S1759= | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as COSV60619872; called by muse, mutect2, varscan2
- NDNF | c.1554C>T p.F518= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV65633997; called by muse, mutect2, varscan2
- NXNL1 | c.99G>T p.R33= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV57325148; called by muse, mutect2, varscan2
- OR2T33 | c.366G>A p.A122= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs757226382, COSV58813596, COSV58814743; called by muse, mutect2, varscan2
- PATJ | c.3399G>A p.L1133= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1218205514, COSV57170124, COSV99054304; called by muse, mutect2, varscan2
- PDGFRA | c.516C>T p.Y172= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1046079554, COSV57272471; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIK3R4 | c.1062T>C p.I354= | Silent (SNP) | VAF 71/186 reads (38%) | catalogued as COSV63243498; called by muse, mutect2, varscan2
- PLOD1 | c.789C>T p.F263= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs908800499, COSV52149643; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKCA | c.366C>G p.L122= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs1248095695, COSV52593565, COSV99434999; called by muse, mutect2, varscan2
- RER1 | c.114C>T p.P38= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100087738, COSV60384324; called by muse, mutect2, varscan2
- RFLNA | c.489C>G p.R163= (on ENST00000546355 / NM_001365156.1; = p.R82= on NM_181709.4) | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV58038849; called by muse, mutect2, varscan2
- SCN7A | c.4014C>T p.Y1338= | Silent (SNP) | VAF 83/129 reads (64%) | catalogued as COSV69274146; called by muse, mutect2, varscan2
- SLC35E1 | c.792C>T p.L264= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV68736423; called by muse, mutect2, varscan2
- SLC36A4 | c.675C>T p.F225= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs1443297036, COSV58397431; called by muse, mutect2, varscan2
- TEDDM1 | c.699G>C p.L233= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV62380649; called by muse, mutect2, varscan2
- TLN1 | c.3108G>A p.T1036= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs376495117; called by mutect2, varscan2
- TLX2 | c.609G>C p.T203= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52045169, COSV52047002; called by muse, mutect2, varscan2
- USP9X | c.2886A>T p.T962= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV61074110; called by muse, mutect2, varscan2
- ZNF646 | c.1644G>T p.P548= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100336507, COSV56214901; called by muse, mutect2
- AGAP7P | n.1168C>T | RNA (SNP) | VAF 26/164 reads (16%) | catalogued as rs1554941219; called by muse, mutect2, varscan2
- CAMKK2 | c.-111C>A | 5'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as rs1203878131, COSV100242741; called by muse, varscan2
- DCHS2 | n.5142C>T | RNA (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100601436; called by muse, mutect2, varscan2
- HTR3A | c.917-47C>A | Intron (SNP) | VAF 12/84 reads (14%) | catalogued as COSV55471088; called by muse, mutect2, varscan2
- POM121 | chr7:72948703 G>C | 3'Flank (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99987892; called by muse, mutect2, varscan2
- RAPGEF1 | c.1855-2957C>T | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- RPN2 | c.1883+1708G>A | Intron (SNP) | VAF 5/12 reads (42%) | catalogued as COSV52903464; called by muse, mutect2, varscan2
- TMPRSS3 | c.-59G>T | 5'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as COSV52306858; called by muse, mutect2
- UACA | c.79-2235T>G | Intron (SNP) | VAF 20/65 reads (31%) | catalogued as COSV59858887; called by muse, mutect2, varscan2
